Gene-level copy-number profile of tumor specimen C3N-01167-01 (profiled together with C3N-01167-02) from CPTAC case C3N-01167, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 77.1 years (28,149 days).
Specimen C3N-01167-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 77e3bed2-1084-4640-85e5-b513a3fac76f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01167-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/e3996148-76b2-4d30-95ed-6db681ce311d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13,643; copy number 2: 35,444; copy number 3: 7,490; copy number 4: 1,562; copy number 5: 134; copy number 6: 61; copy number 10: 46; copy number 12: 21.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 262 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:88,317,156–88,950,928, 5 genes, copy number 5: ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2.
- chr9:32,384,603–35,149,184, 128 genes, copy number 6–12 (broad region; genes not listed).
- chr17:18,476,737–18,551,705, 5 genes, copy number 5 (within-gene range 1–5): LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr18:20,946,906–27,190,698, 124 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,643. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
